Somatic mutation profile of tumor specimen TCGA-21-1083-01A (aliquot TCGA-21-1083-01A-01D-1521-08) from TCGA case TCGA-21-1083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-21-1083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fcb7c1e-6403-456b-b11e-867780d41913.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1083-11A (Solid Tissue Normal), aliquot TCGA-21-1083-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efe041aa-1354-4c5f-907d-4301276734c2

The open-access MAF lists 779 somatic variants for this specimen: 613 protein-altering or splice-affecting, 145 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 533, Silent 145, Nonsense Mutation 40, Frame Shift Del 20, Splice Site 13, Intron 9, RNA 8, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, 3'UTR 1, Translation Start Site 1.

Variants (750 of 779; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 118/225 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 90/275 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10846G>T p.A3616S | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV71292577; called by muse, mutect2, varscan2
- ABCG8 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs373610655; called by muse, mutect2, varscan2
- ABRAXAS2 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 96/159 reads (60%) | catalogued as rs1322334175; called by muse, mutect2, varscan2
- ACACB | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 271/840 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.61); catalogued as COSV58141287; called by muse, mutect2, varscan2
- ACP4 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1328817906; called by muse, mutect2, varscan2
- ADAM18 | c.1231-1G>T p.X411_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | catalogued as COSV55850898, COSV99694929; called by muse, mutect2, varscan2
- ADAM18 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV55855051; called by muse, mutect2, varscan2
- ADAMTS12 | c.2620C>G p.Q874E | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV61270116; called by muse, mutect2, varscan2
- ADCY10 | c.2224A>T p.K742* | Nonsense Mutation (SNP) | VAF 93/238 reads (39%) | catalogued as COSV100896614, COSV63240116; called by muse, mutect2, varscan2
- ADGRB3 | c.4376G>T p.S1459I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99484119; called by muse, mutect2, varscan2
- ADGRL3 | c.2483C>A p.A828D (on ENST00000506720 / NM_001322402.2; = p.A760D on NM_015236.6) | Missense Mutation (SNP) | VAF 172/316 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV72229455, COSV72230768; called by muse, varscan2
- ADNP2 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490543133, COSV51536849; called by muse, mutect2, varscan2
- AGAP6 | c.1233G>T p.W411C (on ENST00000374056 / NM_001365867.1; = p.W434C on NM_001077665.2) | Missense Mutation (SNP) | VAF 77/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929041; called by muse, varscan2
- AHCTF1 | c.3131G>A p.R1044Q (on ENST00000366508; = p.R1018Q on NM_015446.5) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs138283580; called by muse, mutect2, varscan2
- ALK | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs374136388, COSV66564829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD1 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as rs1189693289; called by muse, mutect2, varscan2
- ANK1 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV55872662; called by muse, mutect2, varscan2
- ANO4 | c.1311G>C p.W437C (on ENST00000392977 / NM_001286615.2; = p.W402C on NM_178826.4) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153592, COSV54614380; called by muse, mutect2, varscan2
- AOX1 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101022029; called by muse, mutect2, varscan2
- ARFGAP1 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100796633; called by muse, mutect2, varscan2
- ARMC4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99518237; called by muse, varscan2
- ARRDC2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.428); catalogued as COSV55846075; called by muse, mutect2, varscan2
- ARSH | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV66962659; called by muse, mutect2, varscan2
- ATP8B3 | c.2981G>A p.C994Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs765772835; called by muse, mutect2, varscan2
- BCO1 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 121/216 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99257860; called by muse, mutect2, varscan2
- BCOR | c.902C>G p.S301C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV60712617; called by muse, mutect2
- BRCA1 | c.2963C>G p.S988* | Nonsense Mutation (SNP) | VAF 119/356 reads (33%) | catalogued as CM030788, COSV58794810; called by muse, mutect2, varscan2
- BRCA1 | c.2666C>G p.S889C | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58801122; called by muse, mutect2, varscan2
- BRD2 | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as rs1218388178; called by muse, mutect2, varscan2
- C7 | c.1487C>A p.A496E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs956474428; called by muse, mutect2, varscan2
- CACNA1E | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.13); catalogued as COSV100703618; called by muse, mutect2, varscan2
- CACNA2D2 | c.1296C>A p.N432K | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56561534; called by muse, mutect2, varscan2
- CACNG3 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50068726, COSV50070085, COSV50078325; called by muse, mutect2, varscan2
- CAMTA1 | c.2212G>C p.G738R | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV100349098, COSV100350713; called by muse, mutect2, varscan2
- CANX | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 238/699 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as COSV56004337; called by muse, mutect2, varscan2
- CD300A | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100177833; called by muse, mutect2, varscan2
- CES5A | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs137860220; called by muse, mutect2
- CFAP221 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as rs752357355, COSV54654594, COSV99733007; called by muse, mutect2, varscan2
- CFH | c.1985G>C p.R662T | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV66411243; called by muse, mutect2, varscan2
- CFHR5 | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99887989; called by muse, mutect2, varscan2
- CHAT | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs141881680, COSV60334982; called by muse, mutect2, varscan2
- CLCN5 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs781834071; called by muse, mutect2, varscan2
- CLINT1 | c.1726A>T p.M576L | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758692113; called by muse, mutect2, varscan2
- CNOT1 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV104395768; called by muse, mutect2, varscan2
- COL24A1 | c.4267G>A p.G1423S | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303133058; called by muse, mutect2, varscan2
- COL2A1 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as CM152036; called by muse, mutect2, varscan2
- COL3A1 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104394805; called by muse, mutect2, varscan2
- COL6A6 | c.4523G>T p.R1508L | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as COSV100650050, COSV62038152; called by muse, mutect2, varscan2
- CR1 | c.1675G>T p.D559Y (on ENST00000367051; = p.D1009Y on NM_000651.6) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100887401; called by mutect2, varscan2
- CRIM1 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 69/335 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs369675156, COSV54874356; called by muse, mutect2, varscan2
- CSMD3 | c.10529G>A p.R3510K (on ENST00000297405 / NM_001363185.1; = p.R3341K on NM_052900.3) | Missense Mutation (SNP) | VAF 125/233 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764049965; called by muse, mutect2, varscan2
- CSMD3 | c.4580C>A p.A1527E (on ENST00000297405 / NM_001363185.1; = p.A1423E on NM_052900.3) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52334489; called by muse, mutect2, varscan2
- CSMD3 | c.3916C>G p.L1306V (on ENST00000297405 / NM_001363185.1; = p.L1202V on NM_052900.3) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs936727664, COSV99848959; called by muse, mutect2, varscan2
- CYLC2 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66338398, COSV66339743; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60479126, COSV60479633; called by muse, mutect2, varscan2
- DDX41 | c.434+1G>A p.X145_splice | Splice Site (SNP) | VAF 51/143 reads (36%) | catalogued as COSV100286394; called by muse, mutect2, varscan2
- DEFB112 | c.90T>A p.S30R | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1012164398, COSV100452168; called by muse, mutect2, varscan2
- DGKG | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV53972592; called by muse, mutect2, varscan2
- DIS3 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 42/143 reads (29%) | catalogued as rs776543561, COSV100899825; called by muse, mutect2, varscan2
- DSC1 | c.2317G>T p.G773* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | catalogued as COSV57145841; called by muse, mutect2, varscan2
- DTWD2 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV100407012; called by muse, mutect2, varscan2
- EPHA10 | c.2776G>T p.D926Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361123; called by muse, mutect2, varscan2
- ERAP2 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV65941049; called by muse, mutect2, varscan2
- ERBB4 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53524670, COSV99631378; called by muse, mutect2, varscan2
- EXOC2 | c.2436+1G>T p.X812_splice | Splice Site (SNP) | VAF 76/293 reads (26%) | catalogued as COSV100032868; called by muse, mutect2, varscan2
- EXOC8 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV50478912; called by muse, mutect2, varscan2
- F13B | c.1262T>A p.V421E | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM103611; called by muse, mutect2, varscan2
- FAM13C | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 135/356 reads (38%) | catalogued as rs1402392418, COSV53255118; called by muse, mutect2, varscan2
- FCGR2C | c.582C>G p.H194Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100912528; called by muse, mutect2, varscan2
- FLG | c.8773G>A p.D2925N | Missense Mutation (SNP) | VAF 162/781 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV100910564; called by muse, mutect2, varscan2
- FREM2 | c.6253G>A p.D2085N | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1475945300; called by muse, mutect2, varscan2
- GABRG2 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV99054935; called by muse, mutect2, varscan2
- GAD2 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761992421; called by muse, varscan2
- GALC | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV54323724; called by muse, mutect2, varscan2
- GALNT17 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.302); catalogued as COSV61171297, COSV61178418; called by muse, mutect2, varscan2
- GBA3 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV101545473, COSV72438612; called by muse, mutect2, varscan2
- GGH | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs538903371; called by muse, mutect2, varscan2
- GPC5 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV65582016; called by muse, mutect2, varscan2
- GPX5 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 194/332 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1343748604; called by muse, mutect2, varscan2
- HGF | c.1851G>T p.W617C | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55951307; called by muse, mutect2, varscan2
- HK2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 291/845 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs773701506; called by muse, mutect2, varscan2
- HOXC10 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs747352685, COSV57726960; called by muse, mutect2, varscan2
- IFNA4 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs200551386, COSV101427011, COSV70179858; called by muse, mutect2, varscan2
- IFT81 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99655660; called by muse, mutect2, varscan2
- IGKV2D-29 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV101534374; called by muse, varscan2
- ITIH5 | c.1544C>A p.A515E | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668672; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1400434352; called by mutect2, varscan2
- KCNG1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457752627, COSV65369000; called by muse, mutect2, varscan2
- KCNH5 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59753801; called by muse, mutect2, varscan2
- KCNH7 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59811411; called by muse, mutect2, varscan2
- KCNJ12 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV59166180; called by muse, mutect2, varscan2
- KCNK10 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069111, COSV56641030; called by muse, mutect2, varscan2
- KDM5C | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100948908; called by muse, mutect2, varscan2
- KDM6A | c.2077G>T p.G693W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1044524871; called by muse, mutect2, varscan2
- KHDC3L | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV64863056; called by muse, mutect2, varscan2
- KIF27 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV99926686; called by muse, mutect2, varscan2
- KIR2DL1 | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 70/455 reads (15%) | catalogued as COSV99382684; called by muse, varscan2
- KLHL1 | c.1346C>G p.P449R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs753185463, COSV64775572, COSV64787031; called by muse, mutect2, varscan2
- KLHL4 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.157); catalogued as COSV64148468; called by muse, mutect2, varscan2
- KLHL7 | c.1639G>A p.E547K (on ENST00000339077 / NM_001031710.3; = p.E499K on NM_018846.5) | Missense Mutation (SNP) | VAF 120/205 reads (59%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); catalogued as rs370732317; called by muse, mutect2, varscan2
- KMT2D | c.5224G>T p.E1742* | Nonsense Mutation (SNP) | VAF 120/194 reads (62%) | catalogued as COSV56481520; called by muse, mutect2, varscan2
- KMT2D | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1323918085; called by muse, mutect2, varscan2
- KRT20 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 173/505 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as COSV51425044; called by muse, mutect2, varscan2
- KRTAP19-4 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); catalogued as rs1235839260; called by muse, mutect2, varscan2
- LHCGR | c.1939_1940insA p.R647Qfs*3 | Frame Shift Ins (INS) | VAF 115/368 reads (31%) | catalogued as COSV99683210; called by mutect2, pindel, varscan2
- LMO7 | c.4916C>A p.S1639Y (on ENST00000357063; = p.S1320Y on NM_005358.5) | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV58530329; called by muse, mutect2, varscan2
- LNPEP | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 108/337 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV51479659; called by muse, mutect2, varscan2
- LRIT1 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372728854; called by muse, mutect2, varscan2
- LRP12 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52627635; called by muse, mutect2, varscan2
- LRP1B | c.11178C>G p.N3726K | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV101261602; called by muse, mutect2, varscan2
- LRP1B | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1224225080; called by muse, mutect2, varscan2
- LRP1B | c.2765G>T p.C922F | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63341637; called by muse, mutect2, varscan2
- LRRC8A | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as rs1356244793; called by muse, mutect2, varscan2
- LVRN | c.2835G>A p.L945= | Splice Region (SNP) | VAF 42/104 reads (40%) | catalogued as rs750399390; called by muse, mutect2, varscan2
- MAEL | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99057621; called by muse, mutect2, varscan2
- MAGEC3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs370315828, COSV74217389; called by muse, mutect2, varscan2
- MAP4K1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs770505238; called by muse, mutect2, varscan2
- MATN2 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765751317; called by muse, mutect2, varscan2
- MATN4 | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | PolyPhen probably damaging (0.998); catalogued as COSV100637084, COSV100637122; called by muse, mutect2, varscan2
- MBD5 | c.3588G>T p.Q1196H | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV68695834; called by muse, mutect2, varscan2
- MMP17 | c.1322A>G p.D441G | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1321584847; called by muse, mutect2, varscan2
- MON1B | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50247386; called by muse, mutect2
- MUC16 | c.26399G>T p.G8800V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as rs758795123, COSV67492955; called by muse, mutect2, varscan2
- MUC16 | c.26398G>A p.G8800S | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.556); catalogued as rs769472638, COSV101200624; called by muse, mutect2, varscan2
- MYCN | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55260389, COSV55261356; called by muse, mutect2, varscan2
- N4BP2L2 | c.2107A>G p.T703A (on ENST00000674422; = p.T274A on NM_033111.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs1462904647; called by muse, mutect2, varscan2
- NBEA | c.6773G>T p.G2258V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59759569, COSV99060790; called by muse, mutect2, varscan2
- NCAM2 | c.595del p.R199Vfs*30 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | catalogued as COSV53070591; called by mutect2, pindel, varscan2
- NCAPG2 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1339546833; called by muse, mutect2, varscan2
- NCKAP1 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs200960008; called by muse, mutect2, varscan2
- NDST4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs755372289, COSV52142690; called by muse, mutect2, varscan2
- NDUFS1 | c.2093-1G>T p.X698_splice | Splice Site (SNP) | VAF 61/167 reads (37%) | catalogued as COSV99260429; called by muse, mutect2, varscan2
- NHS | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66271473; called by muse, mutect2, varscan2
- NID1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs750625934, COSV51615363; called by muse, mutect2, varscan2
- NLRC3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs778397189, COSV57095140; called by muse, mutect2, varscan2
- NOTCH1 | c.7322C>G p.A2441G | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV53057688; called by muse, mutect2, varscan2
- NOX4 | c.1443C>A p.N481K | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs763548956; called by muse, mutect2, varscan2
- NPAP1 | c.2288C>G p.P763R | Missense Mutation (SNP) | VAF 222/389 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61512227; called by muse, mutect2, varscan2
- NT5E | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200840390; called by muse, mutect2, varscan2
- NUP205 | c.5902A>G p.I1968V | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs368180701; called by muse, mutect2, varscan2
- NUP210L | c.5350G>A p.V1784M | Missense Mutation (SNP) | VAF 151/374 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1450498063; called by muse, mutect2, varscan2
- NXF3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as COSV101221906; called by muse, mutect2, varscan2
- OLFML2B | c.2162C>G p.T721R | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54200065; called by muse, mutect2, varscan2
- OMP | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV99582284; called by muse, mutect2, varscan2
- OPCML | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762120321, COSV59404700; called by muse, mutect2, varscan2
- OR11H1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 141/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99421594, COSV99421966; called by muse, mutect2, varscan2
- OR1M1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754863155, COSV70036813; called by muse, mutect2, varscan2
- OR2L13 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1208138847, COSV63564022; called by muse, mutect2, varscan2
- OR2L8 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV100594040; called by muse, mutect2, varscan2
- OR4A15 | c.547T>A p.L183M | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59035522; called by muse, mutect2, varscan2
- OR4K2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 222/724 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs772191565, COSV100064150; called by muse, varscan2
- OR51B5 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56176544; called by muse, mutect2, varscan2
- OR5AC2 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV62279541; called by muse, mutect2, varscan2
- OR5M3 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs201997492, COSV56567819; called by muse, varscan2
- OR9A4 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 139/378 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); catalogued as rs782482254, COSV71885099; called by muse, varscan2
- PCDH11X | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.196); catalogued as COSV100008496; called by muse, mutect2, varscan2
- PCDH11X | c.3611C>T p.T1204I | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100008505; called by muse, mutect2, varscan2
- PCDH18 | c.3364G>T p.V1122L | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100787326; called by muse, mutect2, varscan2
- PCDHB5 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 162/399 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.056); catalogued as COSV50654544, COSV99167656; called by muse, mutect2, varscan2
- PCDHGB4 | c.1339G>C p.A447P | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.041); catalogued as COSV53989324; called by muse, mutect2, varscan2
- PCDHGB6 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs759945612; called by muse, mutect2, varscan2
- PDE10A | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370604056; called by muse, mutect2, varscan2
- PDILT | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.289); catalogued as rs144890989, COSV56699975; called by muse, mutect2, varscan2
- PIK3R6 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.357); catalogued as COSV61004280; called by muse, mutect2, varscan2
- PKHD1L1 | c.4216G>A p.G1406S | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780000649; called by muse, mutect2, varscan2
- PLCB1 | c.1617A>T p.E539D | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV62037575; called by muse, mutect2, varscan2
- PLEC | c.12887G>C p.R4296P (on ENST00000322810 / NM_201380.4; = p.R4186P on NM_000445.5) | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59647172; called by muse, mutect2, varscan2
- PNPLA2 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs1311535778; called by muse, varscan2
- POTEE | c.2080C>G p.L694V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs571742663; called by muse, varscan2
- POTEE | c.2141C>G p.S714C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100387049; called by muse, varscan2
- PTBP1 | c.905C>T p.P302L (on ENST00000349038 / NM_031991.4; = p.P328L on NM_002819.5) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs746526932; called by muse, mutect2, varscan2
- PTPN22 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63084630; called by muse, mutect2, varscan2
- PTPRN | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55346726; called by muse, mutect2, varscan2
- PXDNL | c.3372G>T p.Q1124H | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100687027; called by muse, mutect2, varscan2
- RADIL | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101271638; called by muse, mutect2, varscan2
- RASA3 | c.1665G>C p.K555N | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100481029; called by muse, mutect2, varscan2
- RELN | c.3591C>A p.F1197L | Missense Mutation (SNP) | VAF 179/579 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59003987; called by muse, mutect2, varscan2
- RNF217 | c.1281+1G>T p.X427_splice (on ENST00000521654 / NM_001286398.2; = p.X135_splice on NM_152553.5) | Splice Site (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99254834; called by muse, mutect2
- SEC11A | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV99190171; called by muse, mutect2, varscan2
- SEC14L3 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs570127053; called by muse, mutect2, varscan2
- SELE | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60973772; called by muse, mutect2, varscan2
- SEPTIN2 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV63633519; called by muse, mutect2, varscan2
- SERPINB12 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 264/323 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771057082; called by muse, mutect2, varscan2
- SERPINB3 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192006, COSV52193818; called by muse, mutect2, varscan2
- SGCD | c.519C>A p.F173L (on ENST00000435422 / NM_001128209.2; = p.F174L on NM_000337.5) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV61918514; called by muse, mutect2, varscan2
- SGIP1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV52764607; called by muse, mutect2, varscan2
- SI | c.4267+1G>A p.X1423_splice | Splice Site (SNP) | VAF 48/162 reads (30%) | catalogued as rs199897248, COSV100014159; called by muse, varscan2
- SLC5A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV99833217; called by muse, mutect2, varscan2
- SLITRK2 | c.1887C>A p.F629L | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59422958; called by muse, mutect2, varscan2
- SMG1 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs761215949, COSV101245240; called by muse, mutect2, varscan2
- SMURF2 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99300219; called by muse, mutect2, varscan2
- SPTBN4 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58955117; called by muse, mutect2, varscan2
- STK36 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55329085; called by muse, mutect2, varscan2
- SYT1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV54049842; called by muse, mutect2, varscan2
- TAAR1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99257483; called by muse, mutect2, varscan2
- TACR3 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777530972, COSV59199110, COSV59201153; called by muse, mutect2, varscan2
- TBC1D17 | c.927+1G>T p.X309_splice | Splice Site (SNP) | VAF 54/112 reads (48%) | catalogued as rs200802990, COSV99680418; called by muse, mutect2, varscan2
- TDGF1 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 65/117 reads (56%) | catalogued as rs756132962; called by muse, mutect2, varscan2
- TEX43 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs770108067; called by muse, mutect2, varscan2
- TGM6 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52479748; called by muse, mutect2, varscan2
- TMEM200A | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774068784; called by muse, mutect2, varscan2
- TNN | c.3062G>T p.R1021L | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as COSV53434768; called by muse, mutect2, varscan2
- TRAV8-3 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs1457909560; called by muse, mutect2, varscan2
- TRIM29 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100531666; called by muse, mutect2, varscan2
- TRIM58 | c.652A>T p.S218C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV63569906; called by muse, mutect2, varscan2
- TRIM58 | c.1073G>T p.W358L | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63569515, COSV63571737; called by muse, mutect2, varscan2
- TRIM58 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825193; called by muse, mutect2, varscan2
- TRPA1 | c.2978G>T p.W993L | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV51563874, COSV51569055; called by muse, mutect2, varscan2
- TRPC7 | c.240C>G p.N80K | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372900766, COSV61456123; called by muse, mutect2, varscan2
- TRUB2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540243770; called by muse, mutect2, varscan2
- TTN | c.102310T>A p.S34104T (on ENST00000591111; = p.S26680T on NM_003319.4) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | PolyPhen benign (0.068); catalogued as COSV60196412; called by muse, mutect2, varscan2
- TTN | c.97852G>C p.E32618Q (on ENST00000591111; = p.E25194Q on NM_003319.4) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | PolyPhen possibly damaging (0.856); catalogued as COSV60223081; called by muse, mutect2, varscan2
- TTN | c.85180C>A p.R28394S (on ENST00000591111; = p.R20970S on NM_003319.4) | Missense Mutation (SNP) | VAF 52/133 reads (39%) | PolyPhen benign (0.372); catalogued as COSV60002845; called by muse, mutect2, varscan2
- TTN | c.79651G>C p.E26551Q (on ENST00000591111; = p.E19127Q on NM_003319.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | PolyPhen probably damaging (0.997); catalogued as COSV60047934; called by muse, mutect2, varscan2
- TTN | c.79359G>C p.K26453N (on ENST00000591111; = p.K19029N on NM_003319.4) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | PolyPhen probably damaging (0.997); catalogued as COSV60069665; called by muse, mutect2, varscan2
- UBE2D3 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV57660365; called by muse, mutect2, varscan2
- UPK1B | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs755357574, COSV51767219; called by muse, mutect2, varscan2
- USP34 | c.2501-1G>T p.X834_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV68405060; called by muse, mutect2
- VPS13B | c.7852C>A p.Q2618K | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV62133677; called by muse, mutect2
- XIRP2 | c.5302G>T p.G1768C (on ENST00000628543; = p.G1943C on NM_152381.6) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV54714082; called by muse, mutect2, varscan2
- XKR5 | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101306628, COSV68398402; called by muse, mutect2, varscan2
- YIPF4 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs780167554; called by muse, mutect2, varscan2
- ZFC3H1 | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66432073; called by muse, mutect2, varscan2
- ZFPM2 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1437224917; called by muse, mutect2
- ZNF138 | c.328G>T p.G110C (on ENST00000307355 / NM_001367572.1; = p.G84C on NM_006524.4) | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.882); catalogued as COSV56464604; called by muse, mutect2
- ZNF154 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs752065572; called by muse, mutect2, varscan2
- ZNF347 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1198751239; called by muse, mutect2, varscan2
- ZNF426 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV53469129; called by muse, mutect2, varscan2
- ZNF573 | c.1354A>G p.T452A (on ENST00000536220 / NM_001172692.1; = p.T394A on NM_152360.3) | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.281); catalogued as rs758426457; called by muse, mutect2, varscan2
- ZNF574 | c.2308G>C p.D770H | Missense Mutation (SNP) | VAF 74/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55905712, COSV55906893, COSV55907568; called by muse, mutect2, varscan2
- ZNF98 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100757308; called by muse, mutect2, varscan2
- A1CF | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTS19 | c.1858T>A p.C620S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS19 | c.3298G>T p.G1100C | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS20 | c.4499G>A p.C1500Y | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRE3 | c.1714G>T p.V572L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADGRL1 | c.752C>A p.T251N (on ENST00000340736 / NM_001008701.3; = p.T246N on NM_014921.5) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.3506G>T p.G1169V | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADSS2 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AFF3 | c.2593G>T p.V865L | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKT2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH8A1 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKAR | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANKRD33 | c.233G>T p.C78F (on ENST00000340970 / NM_001304459.2; = p.X213_splice on NM_182608.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ANKS1B | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- AP000311.1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.39); called by muse, mutect2, varscan2
- AQP12A | c.98C>G p.A33G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ARHGAP32 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARMC4 | c.423T>A p.Y141* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | called by muse, varscan2
- ARPP21 | c.1202G>T p.S401I | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARX | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- ASH1L | c.1858C>G p.H620D | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ATF7IP | c.2136del p.Q714Kfs*4 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- ATG4C | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ATP12A | c.365del p.G122Afs*21 | Frame Shift Del (DEL) | VAF 191/816 reads (23%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AVPR1B | c.1194T>A p.S398R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BFSP2 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- C12orf50 | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CA12 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 61/97 reads (63%) | called by muse, mutect2, varscan2
- CA4 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CA6 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CACNB2 | c.1399C>A p.P467T (on ENST00000324631 / NM_201596.3; = p.P412T on NM_000724.4) | Missense Mutation (SNP) | VAF 133/406 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNG3 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CAMSAP2 | c.4190A>G p.N1397S (on ENST00000236925 / NM_001297707.2; = p.N1386S on NM_203459.3) | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CASS4 | c.791C>G p.A264G | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC110 | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCL5 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCR10 | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCSER1 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CD22 | c.617T>G p.F206C | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CD5L | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CDC27 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDR1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEACAM3 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CEP350 | c.1428G>T p.R476S | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CHRD | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CHRM3 | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CHUK | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CNTN5 | c.3183G>T p.R1061S | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL5A3 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPA3 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CPPED1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSMD3 | c.7222A>T p.T2408S (on ENST00000297405 / NM_001363185.1; = p.T2304S on NM_052900.3) | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CSMD3 | c.2960C>A p.T987K (on ENST00000297405 / NM_001363185.1; = p.T883K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSN3 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CSPP1 | c.3652A>G p.T1218A (on ENST00000676605; = p.T1177A on NM_024790.6) | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- CSRNP3 | c.1549A>C p.S517R | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CTRB2 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUBN | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- CUL3 | c.596C>A p.S199* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- CUL9 | c.6768A>T p.K2256N | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CYTIP | c.252T>A p.D84E | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- DDB1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- DGKH | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DGKH | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 64/216 reads (30%) | called by muse, mutect2, varscan2
- DHX37 | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- DLEC1 | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DLGAP2 | c.1260del p.T421Pfs*13 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- DLL4 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP7 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- DPY19L1 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DSC2 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DST | c.15646G>A p.A5216T (on ENST00000361203 / NM_001374722.1; = p.A2804T on NM_015548.5) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DYNC2H1 | c.6934C>G p.Q2312E | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- DZIP3 | c.2075A>G p.Q692R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DZIP3 | c.2601A>T p.L867F | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EFHD1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHMT1 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ESYT2 | c.1290C>G p.I430M (on ENST00000613624; = p.I354M on NM_020728.3) | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EXOC2 | c.2436G>T p.E812D | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EYS | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- F11 | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM47C | c.2828T>A p.L943H | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM71B | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAM83H | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAP | c.283A>G p.M95V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FBN2 | c.6416C>A p.P2139H | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FCRL5 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- FGB | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FGF23 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- FGFR4 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FLRT2 | c.1460C>A p.S487Y | Missense Mutation (SNP) | VAF 94/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMNL1 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOLR3 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FOXN1 | c.1848del p.Y617Tfs*59 | Frame Shift Del (DEL) | VAF 36/127 reads (28%) | called by mutect2, pindel, varscan2
- FSCB | c.2438T>G p.V813G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by mutect2, varscan2
- FZD9 | c.1376C>A p.A459D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAS2L2 | c.1084A>T p.R362W | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GEMIN5 | c.2533G>T p.A845S | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GGNBP2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GIGYF2 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GIN1 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GOLGB1 | c.3008A>G p.K1003R | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLIM4 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 57/322 reads (18%) | called by muse, mutect2, varscan2
- GPR179 | c.3424C>T p.Q1142* (on ENST00000621958; = p.Q1141* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 124/352 reads (35%) | called by muse, varscan2
- GPR62 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK3 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- GRK5 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTDC1 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HECTD4 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPF | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HOXD9 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HSD17B4 | c.1181C>T p.S394F (on ENST00000414835 / NM_001199291.3; = p.S369F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HTR3B | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICOS | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT172 | c.1938G>A p.R646= | Splice Region (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IL12B | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IL4R | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- INTS1 | c.964G>C p.A322P | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- INTS8 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- IPCEF1 | c.82A>T p.T28S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO8 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRAK1 | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- IWS1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.7991A>T p.E2664V (on ENST00000360013 / NM_001024660.4; = p.E967V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.363); called by muse, mutect2
- KATNIP | c.4000G>C p.D1334H | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KBTBD8 | c.604A>C p.S202R | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- KCMF1 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ4 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- KCNN1 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNU1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KCTD19 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 236/352 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KDM8 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIAA1755 | c.2251C>A p.P751T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF13B | c.1221G>C p.M407I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- KIR3DL2 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KLK15 | c.573del p.M192Wfs*62 | Frame Shift Del (DEL) | VAF 85/236 reads (36%) | called by mutect2, pindel, varscan2
- KNG1 | c.1773C>G p.I591M | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KRT77 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KRT83 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAS1L | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRIT1 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8570G>T p.C2857F | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LVRN | c.1257C>G p.H419Q | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC3 | c.1438del p.A480Qfs*4 | Frame Shift Del (DEL) | VAF 42/110 reads (38%) | called by mutect2, pindel, varscan2
- MAML1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MAP2 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 173/526 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 142/419 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MB21D2 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 99/414 reads (24%) | called by muse, mutect2, varscan2
- MBOAT1 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MDN1 | c.1038_1056del p.G347Sfs*36 | Frame Shift Del (DEL) | VAF 170/522 reads (33%) | called by mutect2, varscan2
- MKNK1 | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP17 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- MMP9 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MOCOS | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MOGAT3 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MRC2 | c.3103dup p.W1035Lfs*33 | Frame Shift Ins (INS) | VAF 162/499 reads (32%) | called by mutect2, pindel, varscan2
- MRGPRX1 | c.561A>T p.L187F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MRPL51 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A4A | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MTM1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTR | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTREX | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MUC16 | c.42515G>A p.G14172D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.29535C>G p.I9845M | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- MUC17 | c.12568C>G p.L4190V | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MXRA5 | c.7087G>T p.V2363L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- MYG1 | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 151/445 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH13 | c.4120C>A p.Q1374K | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MYH13 | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH15 | c.1394G>T p.R465M | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYH4 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH6 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MYO16 | c.3349C>G p.Q1117E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MYO7A | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO7B | c.1388A>T p.Q463L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYOM2 | c.4372G>T p.A1458S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MYOZ3 | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAV3 | c.5590C>G p.R1864G (on ENST00000397909 / NM_001024383.2; = p.R1842G on NM_014903.6) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBAS | c.3997A>T p.T1333S | Missense Mutation (SNP) | VAF 143/390 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NBEAL1 | c.7222C>T p.H2408Y | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NCOA7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NDST3 | c.2385C>A p.Y795* | Nonsense Mutation (SNP) | VAF 86/154 reads (56%) | called by muse, mutect2, varscan2
- NECTIN3 | c.1351A>G p.K451E | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- NEUROD1 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NEUROD6 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEXMIF | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NFKBIB | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NHS | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NINL | c.2424G>C p.E808D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKX2-5 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, varscan2
- NPFFR1 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1H2 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NRARP | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- NRN1L | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NTSR2 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NUDT6 | c.486A>T p.Q162H | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- OAS3 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OLFM4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- OR10AD1 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OR13A1 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- OR13D1 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 106/199 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR14A16 | c.62T>G p.M21R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2G6 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR4C12 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 152/318 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); called by mutect2, varscan2
- OR4F15 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 187/300 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR4K14 | c.107T>A p.V36E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OR4K2 | c.236del p.P79Qfs*3 | Frame Shift Del (DEL) | VAF 116/623 reads (19%) | called by pindel, varscan2*
- OR5D13 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR8H2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 194/451 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OSBPL8 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OTUD7B | c.308G>C p.S103T | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OXCT1 | c.951G>C p.M317I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PAN3 | c.2391G>C p.Q797H | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PAPPA2 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PAPPA2 | c.2900C>A p.T967N | Missense Mutation (SNP) | VAF 170/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCDHA2 | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA4 | c.2171C>A p.S724Y | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PCDHA9 | c.1586A>T p.E529V | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCDHB6 | c.1064C>A p.P355Q | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHGA6 | c.2126T>G p.I709S | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCGF5 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCNA | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PDZD2 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PGBD1 | c.2205C>G p.C735W | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PGLYRP2 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PGR | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PHC3 | c.1589T>C p.I530T (on ENST00000494943 / NM_001308116.2; = p.I542T on NM_024947.4) | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PHF20 | c.2834A>T p.H945L | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PHTF2 | c.865G>T p.G289C (on ENST00000248550 / NM_001366089.1; = p.G251C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGC | c.653A>T p.K218M | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PIP4K2A | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PKHD1 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PKHD1L1 | c.3433G>T p.G1145W | Missense Mutation (SNP) | VAF 245/470 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PLA2R1 | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PLCB1 | c.1618A>T p.M540L | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PLEC | c.12382G>C p.V4128L (on ENST00000322810 / NM_201380.4; = p.V4018L on NM_000445.5) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEKHH2 | c.3941G>T p.R1314M | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POLR1A | c.844G>T p.G282* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- PRDM9 | c.1462A>G p.R488G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRC1 | c.187dup p.L63Pfs*42 | Frame Shift Ins (INS) | VAF 104/398 reads (26%) | called by mutect2, pindel, varscan2
- PSD2 | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMC2 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- PTPRS | c.3676A>T p.K1226* | Nonsense Mutation (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2
- PUDP | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2
- RAPGEF3 | c.2066A>G p.Y689C (on ENST00000389212; = p.Y647C on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RASAL1 | c.2247C>G p.N749K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RB1CC1 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- RBM14 | c.487del p.D163Tfs*68 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- RBM25 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RC3H2 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- REG3G | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 122/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RELN | c.6835G>T p.E2279* | Nonsense Mutation (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- RELN | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- RGS7 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- RNF112 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF144A | c.359_360del p.C120Sfs*59 | Frame Shift Del (DEL) | VAF 67/226 reads (30%) | called by pindel, varscan2
- RNF157 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ROBO3 | c.2015C>A p.A672D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2
- ROBO4 | c.2565_2566delinsA p.L856Cfs*18 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by pindel, varscan2*
- ROBO4 | c.2250del p.I751Sfs*43 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1565A>G p.Q522R | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RPLP2 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RTBDN | c.657C>A p.S219R (on ENST00000393233 / NM_001270444.1; = p.S251R on NM_031429.2) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- RYR3 | c.3404G>T p.S1135I | Missense Mutation (SNP) | VAF 142/260 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2
- RYR3 | c.3406G>T p.G1136W | Missense Mutation (SNP) | VAF 146/266 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SACS | c.9628G>C p.D3210H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SASS6 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SCAF11 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN3A | c.4086C>A p.Y1362* | Nonsense Mutation (SNP) | VAF 53/189 reads (28%) | called by muse, mutect2, varscan2
- SDR9C7 | c.721A>C p.I241L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELPLG | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SESTD1 | c.2005G>C p.A669P | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SEZ6L2 | c.2651A>G p.Y884C (on ENST00000308713 / NM_001114099.3; = p.Y827C on NM_012410.4) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SF1 | c.539A>T p.K180I | Missense Mutation (SNP) | VAF 257/603 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3GL1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- SHANK2 | c.5108G>T p.G1703V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- SHLD1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- SLC27A4 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SLC3A1 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SLC6A1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC6A12 | c.895del p.Q299Rfs*4 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 207/454 reads (46%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLCO1B1 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, varscan2
- SMCHD1 | c.189A>T p.T63= | Splice Region (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- SNX25 | c.1527G>C p.M509I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOGA3 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SORCS1 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPANXB1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPATA31A1 | c.3827A>T p.Q1276L | Missense Mutation (SNP) | VAF 185/456 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPATA31E1 | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SPATA5 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.3650G>C p.S1217T | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 115/206 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- STAT3 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- STAT5B | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STXBP5 | c.3137G>A p.G1046E (on ENST00000321680 / NM_001127715.2; = p.G1010E on NM_139244.4) | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2C | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 137/241 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SYAP1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- SYNE1 | c.18788C>A p.S6263* (on ENST00000367255 / NM_182961.4; = p.S6192* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- SYNE1 | c.2971G>T p.E991* (on ENST00000367255 / NM_182961.4; = p.E998* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 119/274 reads (43%) | called by muse, mutect2, varscan2
- SYT17 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, varscan2
- SYT17 | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 44/148 reads (30%) | called by muse, varscan2
- SYT2 | c.921C>A p.D307E | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TACR1 | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEDC1 | c.1359G>T p.R453S (on ENST00000392523 / NM_001367178.1; = p.R384S on NM_001134875.1) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TEPSIN | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TESMIN | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET1 | c.6307C>T p.Q2103* | Nonsense Mutation (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- TICAM1 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); called by muse, varscan2
- TJAP1 | c.1082G>T p.S361I (on ENST00000372445 / NM_001146016.1; = p.S351I on NM_080604.3) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLK1 | c.1151G>T p.R384I | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TLL2 | c.1063del p.L355Cfs*37 | Frame Shift Del (DEL) | VAF 27/50 reads (54%) | called by mutect2, pindel, varscan2
- TLR4 | c.536A>T p.H179L (on ENST00000355622 / NM_138554.5; = p.H139L on NM_003266.4) | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM132D | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM132D | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, varscan2
- TMEM219 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM225 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TMEM67 | c.1418A>T p.H473L | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMPRSS11B | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMPRSS11F | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TMPRSS11F | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TNKS2 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TNNI1 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 89/164 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAV8-3 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV5-1 | c.314C>G p.S105W | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM25 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); called by muse, varscan2
- TRIM58 | c.821A>C p.K274T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- TRIM75P | c.78del p.V27Sfs*48 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- TRMT9B | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRO | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM1 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 128/227 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TTN | c.97682T>C p.L32561S (on ENST00000591111; = p.L25137S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.79024G>C p.D26342H (on ENST00000591111; = p.D18918H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TTN | c.78661G>C p.E26221Q (on ENST00000591111; = p.E18797Q on NM_003319.4) | Missense Mutation (SNP) | VAF 52/145 reads (36%) | PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TTN | c.37888C>G p.P12630A (on ENST00000591111; = p.P5206A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/139 reads (29%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.10604A>C p.Q3535P (on ENST00000591111; = p.Q3489P on NM_003319.4) | Missense Mutation (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.3472G>A p.V1158I (on ENST00000591111; = p.V1112I on NM_003319.4) | Missense Mutation (SNP) | VAF 52/153 reads (34%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- U2SURP | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- USH2A | c.4048T>A p.S1350T | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.3563C>A p.P1188H | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USP17L2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- USP9X | c.1717A>G p.I573V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, varscan2
- UTRN | c.8127G>C p.E2709D | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VEZT | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 158/427 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- VIM | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- VIP | c.476del p.G159Efs*10 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- VNN2 | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VSTM2L | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WBP2NL | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 208/518 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- WDR1 | c.1513G>A p.A505T (on ENST00000382452; = p.A365T on NM_005112.5) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- XKRX | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPNPEP3 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN2 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XXYLT1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZAN | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ZBED9 | c.2830T>G p.S944A | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX4 | c.6435G>T p.R2145S | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.7030del p.Q2344Kfs*48 | Frame Shift Del (DEL) | VAF 153/365 reads (42%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.10827C>G p.I3609M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2
- ZFP91 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZMYND8 | c.277del p.V93Ffs*23 (on ENST00000311275 / NM_001363741.2; = p.V113Ffs*23 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | called by mutect2, pindel, varscan2
- ZNF37A | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF521 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF558 | c.681G>T p.L227F | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZNF571 | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF582 | c.1008G>C p.R336S | Missense Mutation (SNP) | VAF 123/263 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF610 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF99 | c.1947C>G p.Y649* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- ZNRF4 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZSCAN30 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSWIM2 | c.1244A>C p.H415P | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA13 | c.10845G>T p.L3615= | Silent (SNP) | VAF 55/102 reads (54%) | called by muse, mutect2, varscan2
- ABCC6 | c.624A>C p.A208= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99228102; called by mutect2, varscan2
- AC005833.1 | c.1078C>T p.L360= | Silent (SNP) | VAF 55/166 reads (33%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.1020G>T p.L340= | Silent (SNP) | VAF 100/143 reads (70%) | called by muse, mutect2, varscan2
- ADGRL1 | c.753C>A p.T251= (on ENST00000340736 / NM_001008701.3; = p.T246= on NM_014921.5) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100529271, COSV61564192; called by muse, mutect2, varscan2
- AFAP1L1 | c.1098G>T p.R366= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1487276149; called by muse, mutect2, varscan2
- AKT1S1 | c.444C>T p.P148= (on ENST00000344175 / NM_001098633.4; = p.P168= on NM_032375.5) | Silent (SNP) | VAF 184/384 reads (48%) | catalogued as rs760629319; called by muse, mutect2, varscan2
- AL121899.2 | c.891G>C p.G297= | Silent (SNP) | VAF 73/210 reads (35%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.1521G>A p.V507= | Silent (SNP) | VAF 98/214 reads (46%) | called by muse, mutect2, varscan2
- AMER3 | c.1071C>T p.D357= | Silent (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- ANO4 | c.2196A>T p.L732= (on ENST00000392977 / NM_001286615.2; = p.L697= on NM_178826.4) | Silent (SNP) | VAF 63/227 reads (28%) | called by muse, mutect2, varscan2
- APOB | c.1131C>A p.I377= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV51946357; called by muse, mutect2, varscan2
- BHLHE41 | c.861C>A p.G287= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1341514220; called by muse, mutect2
- BLK | c.883C>A p.R295= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- BOP1 | c.888C>T p.H296= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- C3 | c.3276C>G p.L1092= | Silent (SNP) | VAF 60/332 reads (18%) | called by muse, mutect2, varscan2
- CACNA1C | c.4917T>C p.L1639= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs886049206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBX5 | c.243C>T p.P81= | Silent (SNP) | VAF 102/345 reads (30%) | called by muse, mutect2, varscan2
- CELSR2 | c.4143C>T p.R1381= | Silent (SNP) | VAF 67/162 reads (41%) | catalogued as rs767449979, COSV99604626; called by muse, mutect2, varscan2
- CFTR | c.3783G>A p.L1261= | Silent (SNP) | VAF 59/185 reads (32%) | called by muse, mutect2, varscan2
- CHRM3 | c.1737C>T p.V579= | Silent (SNP) | VAF 59/197 reads (30%) | catalogued as COSV99697197; called by muse, mutect2, varscan2
- CHST13 | c.621C>G p.R207= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- CHST8 | c.9G>A p.L3= | Silent (SNP) | VAF 49/213 reads (23%) | called by muse, mutect2, varscan2
- CNMD | c.288C>T p.N96= | Silent (SNP) | VAF 62/261 reads (24%) | called by muse, mutect2, varscan2
- CPNE4 | c.828T>C p.N276= | Silent (SNP) | VAF 65/223 reads (29%) | catalogued as COSV70200460; called by muse, mutect2, varscan2
- CRAMP1 | c.1389C>T p.C463= | Silent (SNP) | VAF 12/25 reads (48%) | called by mutect2, varscan2
- CST2 | c.366C>A p.I122= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs142992719; called by muse, mutect2, varscan2
- CYP11A1 | c.564G>A p.K188= | Silent (SNP) | VAF 98/141 reads (70%) | catalogued as rs1325337548; called by muse, mutect2, varscan2
- DSCAML1 | c.3600C>G p.G1200= (on ENST00000321322; = p.G1140= on NM_020693.4) | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV58398646; called by muse, mutect2, varscan2
- EDC4 | c.4200C>T p.L1400= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs1160454028; called by muse, mutect2, varscan2
- EFHD1 | c.516G>T p.L172= | Silent (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1920G>T p.V640= (on ENST00000346169 / NM_198241.3; = p.V444= on NM_004953.5) | Silent (SNP) | VAF 192/456 reads (42%) | called by muse, mutect2, varscan2
- ELL3 | c.628C>A p.R210= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as rs144962107; called by muse, mutect2, varscan2
- F10 | c.261C>G p.G87= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV65021693; called by muse, mutect2, varscan2
- F5 | c.2538G>C p.G846= | Silent (SNP) | VAF 164/479 reads (34%) | called by muse, mutect2, varscan2
- FAM118B | c.837G>C p.R279= | Silent (SNP) | VAF 168/295 reads (57%) | called by muse, mutect2, varscan2
- FAT3 | c.1329T>C p.Y443= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- FLG | c.2112A>C p.A704= | Silent (SNP) | VAF 377/1199 reads (31%) | called by muse, mutect2, varscan2
- FRY | c.4269G>T p.T1423= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- G6PC2 | c.366C>A p.V122= | Silent (SNP) | VAF 218/639 reads (34%) | called by muse, mutect2, varscan2
- GPR61 | c.681C>A p.V227= | Silent (SNP) | VAF 66/373 reads (18%) | called by muse, varscan2
- GRIK5 | c.666C>T p.I222= | Silent (SNP) | VAF 25/176 reads (14%) | called by muse, mutect2, varscan2
- H2BC4 | c.66G>T p.A22= | Silent (SNP) | VAF 121/219 reads (55%) | called by muse, mutect2, varscan2
- HDAC3 | c.495C>G p.L165= | Silent (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1107C>A p.A369= | Silent (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- HTR4 | c.363C>T p.A121= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- ICAM3 | c.15A>T p.V5= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- IFT140 | c.4388G>A p.*1463= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs1299854506; called by muse, mutect2, varscan2
- ITIH2 | c.1680C>A p.A560= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100623377; called by muse, mutect2, varscan2
- KCNJ3 | c.804C>T p.L268= | Silent (SNP) | VAF 59/200 reads (30%) | called by muse, mutect2, varscan2
- KCNMB4 | c.288T>C p.S96= | Silent (SNP) | VAF 70/209 reads (33%) | catalogued as rs776418718; called by muse, mutect2, varscan2
- KDELR3 | c.30G>T p.L10= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- KIAA0232 | c.1686G>T p.G562= | Silent (SNP) | VAF 109/215 reads (51%) | called by muse, mutect2, varscan2
- KLHDC7A | c.1413C>T p.I471= | Silent (SNP) | VAF 71/128 reads (55%) | called by muse, mutect2, varscan2
- KRTAP19-4 | c.189G>T p.L63= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as COSV61858720; called by muse, mutect2, varscan2
- LILRB4 | c.1224C>A p.P408= (on ENST00000391733 / NM_001278428.3; = p.P407= on NM_001278426.3) | Silent (SNP) | VAF 103/208 reads (50%) | called by muse, mutect2, varscan2
- LRFN2 | c.606G>T p.L202= | Silent (SNP) | VAF 65/120 reads (54%) | called by muse, mutect2, varscan2
- LRRC18 | c.714C>A p.P238= | Silent (SNP) | VAF 166/448 reads (37%) | catalogued as COSV53286279; called by muse, mutect2, varscan2
- LRRC27 | c.1377A>G p.P459= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- MARCHF10 | c.693G>A p.L231= | Silent (SNP) | VAF 144/420 reads (34%) | called by muse, mutect2, varscan2
- MB21D2 | c.453G>T p.R151= | Silent (SNP) | VAF 63/210 reads (30%) | catalogued as COSV101164979; called by muse, mutect2, varscan2
- MICAL2 | c.486A>G p.L162= | Silent (SNP) | VAF 169/305 reads (55%) | called by muse, mutect2, varscan2
- MMP11 | c.1044G>A p.E348= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs1233742821; called by muse, mutect2
- MMP9 | c.738C>A p.T246= | Silent (SNP) | VAF 113/321 reads (35%) | called by muse, mutect2, varscan2
- MROH1 | c.330G>T p.A110= | Silent (SNP) | VAF 135/240 reads (56%) | catalogued as COSV58193275; called by muse, mutect2, varscan2
- MYO10 | c.3231G>A p.Q1077= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57029264; called by muse, mutect2, varscan2
- MYO5A | c.2334A>T p.R778= | Silent (SNP) | VAF 67/95 reads (71%) | called by muse, mutect2, varscan2
- MYO9B | c.4929G>T p.P1643= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- MYT1L | c.2958G>C p.G986= | Silent (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- NBEA | c.7806G>T p.V2602= | Silent (SNP) | VAF 88/232 reads (38%) | called by muse, mutect2, varscan2
- NLRP3 | c.24G>T p.L8= | Silent (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2
- NLRP8 | c.1974G>C p.V658= | Silent (SNP) | VAF 115/238 reads (48%) | called by muse, mutect2, varscan2
- NOP53 | c.1284C>G p.L428= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- OLFML2B | c.1875C>T p.D625= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as rs1379795545, COSV54195135, COSV54195746; called by muse, mutect2, varscan2
- OOEP | c.318G>A p.V106= | Silent (SNP) | VAF 72/143 reads (50%) | called by muse, mutect2, varscan2
- OR10J3 | c.144C>T p.T48= | Silent (SNP) | VAF 114/389 reads (29%) | called by muse, mutect2, varscan2
- OR11H1 | c.234C>A p.V78= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs1342795244, COSV99421999; called by mutect2, varscan2
- OR2W3 | c.201C>T p.S67= | Silent (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- OR4C11 | c.339C>A p.L113= | Silent (SNP) | VAF 62/146 reads (42%) | called by muse, mutect2, varscan2
- OR4C46 | c.711C>A p.T237= | Silent (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- OR51E1 | c.954C>A p.P318= | Silent (SNP) | VAF 71/115 reads (62%) | catalogued as COSV67809350; called by muse, mutect2, varscan2
- OR5AS1 | c.396T>C p.Y132= | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- OR5T3 | c.426C>G p.L142= | Silent (SNP) | VAF 184/403 reads (46%) | called by muse, varscan2
- OR8B4 | c.546C>A p.P182= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV62069226, COSV62069437; called by muse, mutect2, varscan2
- OR8B8 | c.579T>C p.Y193= | Silent (SNP) | VAF 74/160 reads (46%) | catalogued as rs1339861249, COSV60145779; called by muse, mutect2, varscan2
- OR8J1 | c.630C>A p.S210= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV57320361; called by muse, mutect2, varscan2
- OSBPL7 | c.1407G>T p.A469= | Silent (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- OTOA | c.2394C>A p.P798= (on ENST00000286149; = p.P784= on NM_144672.4) | Silent (SNP) | VAF 75/240 reads (31%) | catalogued as COSV99623637; called by muse, mutect2, varscan2
- PANX2 | c.708G>A p.L236= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- PAX4 | c.234G>C p.R78= | Silent (SNP) | VAF 89/306 reads (29%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1785C>T p.R595= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as COSV63546562; called by muse, mutect2, varscan2
- PCDHB13 | c.966A>G p.A322= | Silent (SNP) | VAF 159/443 reads (36%) | catalogued as rs746460308; called by muse, mutect2, varscan2
- PIK3AP1 | c.948C>G p.L316= | Silent (SNP) | VAF 57/107 reads (53%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.1770A>T p.P590= | Silent (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- POPDC2 | c.999T>C p.S333= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs370632589; called by muse, mutect2, varscan2
- PRLR | c.771T>A p.A257= | Silent (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- PRR30 | c.894C>T p.F298= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs549018789; called by muse, mutect2, varscan2
- PTPRC | c.1560G>A p.L520= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- PXDNL | c.1509G>T p.L503= | Silent (SNP) | VAF 216/369 reads (59%) | called by muse, mutect2, varscan2
- RARRES1 | c.381T>G p.S127= | Silent (SNP) | VAF 38/411 reads (9%) | called by muse, mutect2
- RBMXL1 | c.1008A>T p.S336= | Silent (SNP) | VAF 190/460 reads (41%) | called by muse, varscan2
- RIMS2 | c.4371C>T p.I1457= (on ENST00000666250 / NM_001348490.2; = p.I1028= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV51656680; called by muse, mutect2, varscan2
- RNASE2 | c.168C>A p.V56= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs200694912; called by muse, mutect2, varscan2
- RXFP2 | c.2043A>T p.P681= | Silent (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- RYR3 | c.1300C>T p.L434= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as rs756987758; called by muse, mutect2, varscan2
- SAMD9L | c.4602C>A p.I1534= | Silent (SNP) | VAF 69/209 reads (33%) | called by muse, mutect2, varscan2
- SCG2 | c.1188G>A p.E396= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs908820925; called by muse, mutect2, varscan2
- SEMA5A | c.142C>A p.R48= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- SENP7 | c.1944A>G p.E648= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs755830593; called by muse, mutect2, varscan2
- SGCE | c.1194T>C p.S398= (on ENST00000647096; = p.S362= on NM_003919.3) | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- SLC12A7 | c.639G>T p.G213= | Silent (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1593G>A p.E531= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- SLC5A5 | c.174C>G p.P58= | Silent (SNP) | VAF 38/68 reads (56%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.1260C>A p.S420= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99918426; called by muse, varscan2
- SLIT3 | c.408C>T p.T136= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs758379745; called by muse, mutect2, varscan2
- SOD2 | c.93G>A p.L31= | Silent (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- SPIRE1 | c.741G>A p.K247= | Silent (SNP) | VAF 67/105 reads (64%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5406G>T p.A1802= | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.1035C>A p.P345= | Silent (SNP) | VAF 136/434 reads (31%) | called by muse, mutect2, varscan2
- STAT6 | c.207A>G p.G69= | Silent (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
- SYT1 | c.558G>A p.L186= | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as rs1299460181, COSV54031299; called by muse, mutect2, varscan2
- SYT11 | c.741C>T p.L247= | Silent (SNP) | VAF 37/122 reads (30%) | called by muse, varscan2
- SYTL5 | c.168T>A p.T56= | Silent (SNP) | VAF 24/36 reads (67%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2094G>T p.V698= | Silent (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- TDRD7 | c.3237C>T p.T1079= | Silent (SNP) | VAF 114/217 reads (53%) | catalogued as rs150055318; called by muse, mutect2, varscan2
- TECRL | c.495C>A p.I165= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- THRA | c.1170C>A p.G390= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as rs372962433; called by muse, mutect2, varscan2
- TLCD3B | c.423G>T p.L141= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- TMEM132D | c.894C>A p.T298= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV70602152; called by muse, varscan2
- TMEM53 | c.324C>T p.L108= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV62409240; called by muse, mutect2
- TRAPPC9 | c.2673C>G p.T891= | Silent (SNP) | VAF 112/205 reads (55%) | called by muse, mutect2, varscan2
- TRIM3 | c.813C>T p.R271= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as rs557450092; called by muse, mutect2, varscan2
- TRIM49 | c.318G>T p.V106= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV100315896; called by muse, mutect2, varscan2
- TRIM55 | c.792A>G p.S264= | Silent (SNP) | VAF 129/210 reads (61%) | called by muse, mutect2, varscan2
- TSHR | c.426T>A p.P142= | Silent (SNP) | VAF 58/136 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.198G>C p.T66= | Silent (SNP) | VAF 90/235 reads (38%) | catalogued as COSV59884428, COSV60080737; called by muse, mutect2, varscan2
- UBASH3A | c.1479C>A p.I493= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
29 further variants in this file (0 protein-altering or splice-affecting, 8 silent, 21 other) are not listed here.
